Gene-level copy-number profile of tumor specimen TCGA-VS-A8EB-01A from TCGA case TCGA-VS-A8EB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 41.7 years (15,215 days).
Specimen TCGA-VS-A8EB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.37639acb-158f-4ab2-b915-13511bffae44.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A8EB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1640c3e4-7c55-4a0a-8642-dadd582aa388

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 8,408; copy number 3: 14,425; copy number 4: 26,410; copy number 5: 1,697; copy number 6: 3,400; copy number 7: 1,652; copy number 8: 2,484; copy number 9: 315; copy number 10: 361; copy number 13: 299; copy number 15: 3; copy number 16: 19; copy number 17: 31; copy number 18: 41; copy number 19: 50; copy number 21: 27; copy number 23: 23; copy number 24: 162; copy number 26: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A8EB-01A-11D-A36I-01): tumor purity 0.8, ploidy 3.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,317 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:165,122,713–178,385,479, 176 genes, copy number 9–10 (broad region; genes not listed).
- chr3:194,202,392–198,222,513, 151 genes, copy number 10 (broad region; genes not listed).
- chr11:97,657,464–97,657,582, 1 gene, copy number 9: RNA5SP347.
- chr11:98,676,391–103,479,863, 58 genes, copy number 15–26 (within-gene range 2–26): AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1.
- chr12:17,673,299–23,251,499, 77 genes, copy number 9 (broad region; genes not listed).
- chr12:23,637,973–23,638,487, 1 gene, copy number 9: AC087260.1.
- chr12:27,696,388–34,249,958, 144 genes, copy number 9 (broad region; genes not listed).
- chr17:60,008,437–67,697,261, 227 genes, copy number 9–13 (within-gene range 6–13) (broad region; genes not listed).
- chr19:35,042,902–40,576,464, 303 genes, copy number 13–23 (within-gene range 4–23) (broad region; genes not listed).
- chr19:53,365,693–55,087,923, 179 genes, copy number 16–24 (within-gene range 7–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
